Gene-level copy-number profile of tumor specimen TCGA-DK-AA6T-01A from TCGA case TCGA-DK-AA6T, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Trigone of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 63.5 years (23,198 days).
Specimen TCGA-DK-AA6T-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.07cc19f2-720d-4ebc-91cf-ca2737aa078d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DK-AA6T-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/17fcc56e-b683-41f6-9aa0-d845219f4a09

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,189; copy number 2: 45,534; copy number 3: 8,127; copy number 4: 791; copy number 5: 175.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DK-AA6T-01A-11D-A390-01): tumor purity 0.8, ploidy 2.11, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 175 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:4,514,204–8,278,186, 42 genes, copy number 5 (within-gene range 4–5): NPM1P48, LINC01249, AC092169.1, RNU6-649P, AC073143.1, AC107057.1, LINC01248, AC108025.1, SOX11, AC010729.2, AC010729.1, LINC01810, SILC1, MIR7158, AC017053.1, LINC01247, LINC01824, PIK3CDP1, MIR7515HG, AC097517.1, MIR7515, LINC00487, NRIR, CMPK2, RSAD2, AC017076.1, GRASLND, RNF144A, AC068481.1, RN7SKP112, AC010904.2, AC010904.1, AC013460.1, RNU6ATAC37P, AC092580.4, AC092580.2, LINC01871, AC092580.3, AC092580.1, AC007463.1, LINC00298, AC007463.2.
- chr2:8,139,335–8,144,950, 1 gene, copy number 5 (within-gene range 4–5): U91324.1.
- chr2:49,563,388–60,938,604, 130 genes, copy number 5 (broad region; genes not listed).
- chr8:43,672,823–43,674,591, 2 genes, copy number 5: AC139365.2, AC139365.1.

Autosomal genes at a single copy (total copy number 1): 3,376. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
